CCDI case PBCEJN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas.
https://portal.gdc.cancer.gov/cases/bb11cf7f-e08d-485d-9bf0-5da3025cb422

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 7.7 years (2,815 days).

Biospecimens (3 samples)
- Sample 0DPZTG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPZTY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPZUF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
